Somatic mutation profile of tumor specimen TCGA-EE-A3J4-06A (aliquot TCGA-EE-A3J4-06A-11D-A20D-08) from TCGA case TCGA-EE-A3J4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.3 years (29,712 days).
Specimen TCGA-EE-A3J4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b701606c-42a8-4efb-b709-b32d5b8dbc9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3J4-10A (Blood Derived Normal), aliquot TCGA-EE-A3J4-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1618182c-22fb-4aab-9478-2dbd2423313e

The open-access MAF lists 357 somatic variants for this specimen: 249 protein-altering or splice-affecting, 100 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 100, Nonsense Mutation 14, RNA 4, Splice Site 3, Intron 3, Splice Region 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4080T>A p.D1360E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV70026931; called by muse, mutect2, varscan2
- ABCB4 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV55933530; called by muse, mutect2, varscan2
- ABCC9 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53965797; called by muse, mutect2, varscan2
- ABR | c.878C>T p.T293I (on ENST00000302538 / NM_021962.5; = p.T256I on NM_001092.5) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV52143388; called by muse, mutect2, varscan2
- AC006059.2 | c.1259T>G p.I420S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV59606207; called by muse, mutect2, varscan2
- ACTB | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1411316425, COSV100079919; called by muse, mutect2, varscan2
- ACVR1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55117442; called by muse, mutect2, varscan2
- ADAMTS8 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV57292325; called by muse, mutect2, varscan2
- ADGRE3 | c.965T>A p.F322Y | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53729125; called by muse, mutect2, varscan2
- AGO3 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 136/346 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.401); catalogued as COSV55792116; called by muse, varscan2
- AK2 | c.394C>T p.R132C (on ENST00000354858; = p.R174C on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs764104016, COSV61466971; called by muse, mutect2, varscan2
- ALDH16A1 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 270/313 reads (86%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53193244; called by muse, mutect2, varscan2
- ALPK3 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs147903664; called by muse, mutect2, varscan2
- ANAPC1 | c.4774T>C p.F1592L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1372670428, COSV61974894; called by muse, mutect2, varscan2
- ANK3 | c.6532C>T p.P2178S | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55049573; called by muse, mutect2, varscan2
- AP1S1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs760826610, COSV61760476; called by muse, mutect2, varscan2
- APP | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs200103591; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP5 | c.3740T>G p.F1247C (on ENST00000345122 / NM_001030055.2; = p.F1246C on NM_001173.3) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as rs1381763196, COSV61534561; called by muse, mutect2, varscan2
- ARHGEF2 | c.2861G>A p.R954H (on ENST00000361247 / NM_001162383.2; = p.R926H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.033); catalogued as rs1339157141, COSV58108073; called by muse, mutect2, varscan2
- ARPP21 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV51791271, COSV51794362; called by muse, mutect2, varscan2
- ASXL3 | c.5308G>A p.G1770R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52459006; called by muse, mutect2, varscan2
- ATP7B | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as COSV54436550; called by muse, mutect2, varscan2
- BANK1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59838386; called by muse, mutect2, varscan2
- BRINP3 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66517403; called by muse, mutect2, varscan2
- C8orf34 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV61374622; called by muse, mutect2, varscan2
- CAMKV | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); catalogued as COSV104403619, COSV56554638; called by muse, mutect2, varscan2
- CAPS2 | c.794T>G p.M265R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV60824554; called by muse, mutect2, varscan2
- CBWD1 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV58698984; called by muse, mutect2, varscan2
- CCR8 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58336912; called by muse, mutect2, varscan2
- CD79A | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as COSV99702092; called by muse, mutect2, varscan2
- CD79A | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99702094; called by muse, mutect2, varscan2
- CDK11B | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100477023, COSV58337399; called by muse, mutect2, varscan2
- CDK5RAP3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs746686583, COSV58114545; called by muse, mutect2
- CEACAM21 | c.878C>T p.S293F (on ENST00000401445 / NM_001098506.4; = p.S292F on NM_033543.6) | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV51813530; called by muse, mutect2, varscan2
- CENPJ | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV67883185; called by muse, mutect2, varscan2
- CEP350 | c.6377C>T p.S2126F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62600104; called by muse, mutect2, varscan2
- CHD6 | c.7838T>G p.L2613R | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64689190; called by muse, mutect2, varscan2
- CHST8 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52857497; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- COL7A1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.863); catalogued as CM074763, COSV60393146; called by muse, mutect2, varscan2
- CPED1 | c.1135-1G>A p.X379_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100120610, COSV59999024; called by muse, mutect2, varscan2
- CR2 | c.2774T>C p.L925P | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV65506543; called by muse, mutect2, varscan2
- CRISP3 | c.743A>G p.K248R (on ENST00000371159 / NM_001368123.1; = p.K230R on NM_006061.4) | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as rs1384845936, COSV53819673; called by muse, mutect2, varscan2
- CYP2C18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53669788, COSV99608889; called by muse, mutect2, varscan2
- DENND1C | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377613125; called by muse, mutect2, varscan2
- DIP2C | c.3008C>T p.T1003I | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55150876; called by muse, mutect2, varscan2
- DNAH5 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54212862; called by muse, mutect2, varscan2
- DNAH5 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54212875; called by muse, mutect2, varscan2
- DNAH9 | c.11081A>C p.K3694T | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV52340678; called by muse, mutect2, varscan2
- EFHB | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); catalogued as rs780719456, COSV55546010; called by muse, mutect2, varscan2
- EML5 | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1320702541, COSV61343310; called by muse, mutect2, varscan2
- ENAM | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865873089, COSV68535306; called by muse, mutect2, varscan2
- ERCC4 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs763006163, COSV61311214; called by muse, mutect2, varscan2
- ERH | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV53680339; called by muse, mutect2, varscan2
- FAAH2 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 74/94 reads (79%) | catalogued as COSV100887426; called by muse, mutect2, varscan2
- FAAH2 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 71/91 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100887427; called by muse, mutect2, varscan2
- FAM171B | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.715); catalogued as COSV100488818, COSV59001776; called by muse, mutect2, varscan2
- FAM193A | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61194158; called by muse, mutect2, varscan2
- FAT2 | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV55815935; called by muse, mutect2, varscan2
- FCRL3 | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV63840269; called by muse, mutect2, varscan2
- FLT3 | c.331T>G p.S111A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54048325; called by muse, mutect2, varscan2
- FMNL1 | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 59/71 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV58955887; called by muse, mutect2, varscan2
- FN1 | c.3980-1G>A p.X1327_splice | Splice Site (SNP) | VAF 39/106 reads (37%) | catalogued as COSV60548848; called by muse, mutect2
- FNDC7 | c.1419G>A p.M473I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54751939; called by muse, mutect2, varscan2
- FOXD4L5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV101073129; called by mutect2, varscan2
- FOXP2 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63483439, COSV63486063; called by muse, mutect2, varscan2
- FTMT | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs1380320763, COSV58420029; called by muse, mutect2, varscan2
- GABRA2 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV62913216; called by muse, mutect2, varscan2
- GALNT17 | c.1423A>G p.K475E | Missense Mutation (SNP) | VAF 146/633 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.102); catalogued as COSV61153632; called by muse, mutect2, varscan2
- GATA2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV62003654; called by muse, mutect2, varscan2
- GCK | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as CD012260, COSV67884085; called by muse, mutect2, varscan2
- GLI3 | c.3071T>G p.F1024C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV67886575; called by muse, mutect2, varscan2
- GPR37 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58255986; called by muse, mutect2, varscan2
- GRIA1 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53594569, COSV99599217; called by muse, mutect2, varscan2
- GRIN2B | c.3175G>A p.D1059N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205246; called by muse, mutect2, varscan2
- GRK2 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs542501875, COSV57952361; called by muse, mutect2, varscan2
- GRM3 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1363070278, COSV64467002; called by muse, mutect2, varscan2
- GUCY1A1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV56650280; called by muse, mutect2, varscan2
- HEATR5A | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV66339276; called by muse, mutect2, varscan2
- HRC | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs374745031; called by muse, mutect2, varscan2
- HSD11B1L | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as rs1479295822, COSV56797989; called by muse, mutect2
- HSD3B7 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM157057, COSV52680000; called by muse, mutect2, varscan2
- IGHV3-23 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs368753240; called by muse, mutect2, varscan2
- IGSF10 | c.7091A>C p.N2364T | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56373003; called by muse, mutect2, varscan2
- IL16 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs758088675, COSV57261744; called by muse, mutect2, varscan2
- IRF8 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51897163; called by muse, mutect2, varscan2
- ITGAX | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV51643629; called by muse, mutect2, varscan2
- KALRN | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV53757045; called by muse, mutect2, varscan2
- KCNIP1 | c.507G>A p.M169I (on ENST00000411494 / NM_001034837.3; = p.M158I on NM_014592.4) | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV61081925; called by muse, mutect2, varscan2
- KCNMB1 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99211821; called by muse, mutect2, varscan2
- KCNMB1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99211839; called by muse, mutect2, varscan2
- KIF15 | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as COSV58159322; called by muse, mutect2, varscan2
- KIR2DL3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 151/169 reads (89%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1230137764, COSV60896544; called by muse, mutect2, varscan2
- KMT2A | c.2584C>T p.R862* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV63282793; called by muse, mutect2, varscan2
- KMT2B | c.6079G>T p.E2027* | Nonsense Mutation (SNP) | VAF 23/25 reads (92%) | catalogued as rs1404813734, COSV55858924; called by muse, mutect2, varscan2
- KRT25 | c.1157T>G p.L386R | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56444193; called by muse, mutect2, varscan2
- LAMC2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs374263073; called by muse, mutect2, varscan2
- LCE3D | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.994); catalogued as COSV64230634; called by muse, mutect2, varscan2
- LGALS12 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV55369744; called by muse, mutect2, varscan2
- LPA | c.2627G>A p.R876K | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs558138162, COSV60299033, COSV60303648; called by muse, mutect2, varscan2
- LRIF1 | c.900T>G p.F300L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV63896967; called by muse, mutect2, varscan2
- LRRIQ1 | c.2890G>A p.G964S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.861); catalogued as rs751500883, COSV67827681; called by muse, mutect2, varscan2
- LTF | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51606643; called by muse, mutect2, varscan2
- MAEL | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.156); catalogued as rs754539955, COSV63112374; called by muse, mutect2, varscan2
- MAN1A1 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs768644284, COSV63781661; called by muse, mutect2, varscan2
- MAST4 | c.3952C>T p.P1318S (on ENST00000403625 / NM_001164664.2; = p.P1129S on NM_015183.3) | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.31); catalogued as COSV55136751; called by muse, mutect2, varscan2
- MAST4 | c.3953C>T p.P1318L (on ENST00000403625 / NM_001164664.2; = p.P1129L on NM_015183.3) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99845615; called by muse, mutect2, varscan2
- MC3R | c.196A>C p.N66H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54763320; called by muse, mutect2, varscan2
- MEGF8 | c.7420C>T p.R2474C (on ENST00000251268 / NM_001271938.2; = p.R2407C on NM_001410.3) | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753671779, COSV52078701; called by muse, mutect2, varscan2
- MGAM | c.5540A>C p.N1847T | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV72074104; called by muse, mutect2, varscan2
- MGMT | c.260C>T p.P87L (on ENST00000306010; = p.P56L on NM_002412.5) | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs771707610, COSV60023993; called by muse, mutect2, varscan2
- MROH2B | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs866059852, COSV68182327; called by muse, mutect2, varscan2
- MUC15 | c.476A>T p.K159I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV55553554; called by muse, mutect2, varscan2
- MUC16 | c.23035C>T p.P7679S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV67454064; called by muse, mutect2, varscan2
- MUC17 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 207/991 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV60283454; called by muse, mutect2, varscan2
- MUC17 | c.10391C>T p.P3464L | Missense Mutation (SNP) | VAF 225/1073 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as COSV60283464; called by muse, mutect2, varscan2
- MUC2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs780561975; called by muse, mutect2, varscan2
- MYH2 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs866748337, COSV55431027; called by muse, mutect2, varscan2
- MYH4 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV55114596; called by muse, mutect2, varscan2
- MYO1G | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 155/602 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51853920; called by muse, mutect2, varscan2
- NAB2 | c.1078T>A p.L360M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100272781; called by muse, mutect2, varscan2
- NAV3 | c.3293A>T p.K1098I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57069305; called by muse, mutect2, varscan2
- NDST4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs749271707, COSV52112958; called by muse, mutect2, varscan2
- NEU2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as rs184293814, COSV52091946; called by muse, mutect2, varscan2
- NEXMIF | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.084); catalogued as rs927047621, COSV50024189, COSV99279571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKD2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780350408, COSV56890598; called by muse, mutect2, varscan2
- NKRF | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV58660668; called by muse, mutect2
- NPSR1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100707088; called by muse, mutect2, varscan2
- NRK | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54592408; called by muse, mutect2, varscan2
- NRK | c.3596C>T p.P1199L | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54592426; called by muse, mutect2, varscan2
- NSD1 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as COSV61773025; called by muse, mutect2, varscan2
- OBSCN | c.13784G>A p.R4595H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748499455, COSV52755224; called by muse, mutect2, varscan2
- OGDH | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs775279689, COSV56047189; called by muse, mutect2, varscan2
- OGDHL | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100934183, COSV65101574, COSV65104062; called by muse, mutect2, varscan2
- OR10H4 | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59061469; called by muse, mutect2, varscan2
- OR2A12 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV68821165; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV53458913, COSV53460428; called by muse, mutect2
- OR52J3 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as rs146686931; called by muse, mutect2, varscan2
- OR52N5 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.764); catalogued as rs1197540212, COSV57698590; called by muse, mutect2, varscan2
- OR5T2 | c.947T>A p.F316Y | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57588362; called by muse, mutect2, varscan2
- OR8B3 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV63541459; called by muse, mutect2, varscan2
- OR9A4 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV71885181; called by muse, mutect2, varscan2
- OSMR | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57082628; called by muse, mutect2, varscan2
- PAK5 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as COSV62023818; called by muse, mutect2, varscan2
- PAPOLB | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV68199943; called by muse, mutect2, varscan2
- PCDHAC2 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841632; called by muse, mutect2, varscan2
- PCDHB3 | c.917A>C p.Y306S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as rs782438162, COSV50566394; called by muse, mutect2, varscan2
- PCDHB5 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.333); catalogued as rs782400534, COSV50648509; called by muse, mutect2, varscan2
- PEX14 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV63060263; called by muse, mutect2, varscan2
- PGR | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 66/168 reads (39%) | catalogued as COSV54798286; called by muse, mutect2, varscan2
- PLCG1 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV54816666; called by muse, mutect2, varscan2
- PLXDC1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59550165; called by muse, mutect2, varscan2
- PLXNC1 | c.4141C>T p.P1381S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51571896; called by muse, mutect2, varscan2
- POLA1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as rs748009088, COSV66884781; called by muse, mutect2, varscan2
- POTEH | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 73/495 reads (15%) | catalogued as COSV58881377; called by muse, varscan2
- PPM1H | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57372091; called by muse, mutect2, varscan2
- PPP4R4 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58553142; called by muse, mutect2, varscan2
- PRB1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 152/490 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV53702972; called by muse, varscan2
- PRDM13 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65029178; called by muse, mutect2, varscan2
- PSD | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV50043066; called by muse, mutect2, varscan2
- PTGS1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs200616613, COSV56289963; called by muse, mutect2, varscan2
- PTPRB | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV54236582; called by muse, mutect2, varscan2
- PTPRD | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61927343; called by muse, mutect2, varscan2
- PXDN | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs200731840, COSV53229398; called by muse, mutect2, varscan2
- RAN | c.37-1G>T p.X13_splice | Splice Site (SNP) | VAF 56/160 reads (35%) | catalogued as COSV54562242, COSV54562598; called by muse, mutect2, varscan2
- RAPGEF3 | c.2237A>C p.K746T (on ENST00000389212; = p.K704T on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV50199521; called by muse, mutect2, varscan2
- RDX | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV58192705; called by muse, mutect2, varscan2
- RFC1 | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV62898966; called by muse, mutect2, varscan2
- RGMA | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755157637, COSV61233411; called by muse, mutect2, varscan2
- RHOA | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV69041753, COSV69042135; called by muse, mutect2, varscan2
- RIMS2 | c.3662G>A p.W1221* | Nonsense Mutation (SNP) | VAF 169/287 reads (59%) | catalogued as COSV51665085; called by muse, mutect2, varscan2
- RPS8 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV63234356, COSV63234575; called by muse, mutect2, varscan2
- RPTOR | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60806995; called by muse, mutect2, varscan2
- RRM2 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100459817; called by muse, mutect2, varscan2
- RRM2 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100459819; called by muse, mutect2, varscan2
- RRNAD1 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV63928791; called by muse, mutect2, varscan2
- RSBN1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV54731550; called by muse, mutect2, varscan2
- RSF1 | c.2646T>A p.S882R | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV57837849; called by muse, mutect2, varscan2
- SCN1A | c.2657C>T p.S886F (on ENST00000303395 / NM_001202435.3; = p.S875F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57664511; called by muse, mutect2, varscan2
- SCN5A | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61119541; called by muse, mutect2, varscan2
- SCYL3 | c.2078C>T p.P693L (on ENST00000367770; = p.P639L on NM_020423.7) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV53677415; called by muse, mutect2, varscan2
- SEPTIN14 | c.1149G>T p.M383I | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66426856; called by muse, mutect2, varscan2
- SHROOM2 | c.3271G>A p.G1091S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144623135, COSV101099018; called by muse, mutect2, varscan2
- SLC17A6 | c.893A>T p.K298I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV54134564; called by muse, mutect2, varscan2
- SLC17A9 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64846990; called by muse, mutect2, varscan2
- SLC22A2 | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV65265895; called by muse, mutect2, varscan2
- SLCO6A1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65806607, COSV65806881; called by muse, mutect2, varscan2
- SLITRK1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101000010, COSV65674775; called by muse, mutect2, varscan2
- SPEG | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.19); catalogued as COSV56665686; called by muse, mutect2, varscan2
- SPIRE1 | c.1919C>T p.S640L (on ENST00000409402 / NM_001128626.2; = p.S626L on NM_020148.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV59153940; called by muse, mutect2, varscan2
- SPPL2B | c.372C>T p.V124= | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs373935067, COSV66316854; called by muse, mutect2, varscan2
- SPRY3 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57142219; called by muse, mutect2, varscan2
- ST18 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 110/193 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533229892, COSV52488443; called by muse, mutect2, varscan2
- STK38 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 63/84 reads (75%) | catalogued as COSV57707997; called by muse, mutect2, varscan2
- SULF1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1242448114, COSV52676860; called by muse, mutect2, varscan2
- SULF1 | c.2365C>T p.L789F | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52676876, COSV52680037; called by muse, mutect2, varscan2
- SULT1C3 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as rs146012391; called by muse, mutect2, varscan2
- SV2C | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); catalogued as COSV59216325, COSV59230261; called by muse, mutect2, varscan2
- SVEP1 | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57032008; called by muse, mutect2, varscan2
- SYCP1 | c.2043G>A p.E681= | Splice Region (SNP) | VAF 19/53 reads (36%) | catalogued as rs772363056, COSV65695591; called by muse, mutect2, varscan2
- SYK | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65326028; called by muse, mutect2, varscan2
- TAAR6 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV51582972; called by muse, mutect2, varscan2
- TACC2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1241727330, COSV57750407; called by muse, mutect2, varscan2
- TAF1L | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750929210, COSV54259693; called by muse, mutect2, varscan2
- TAS2R1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.587); catalogued as COSV66778301; called by muse, mutect2, varscan2
- TBX15 | c.464C>T p.P155L (on ENST00000369429 / NM_001330677.2; = p.P49L on NM_152380.3) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV52868968; called by muse, mutect2, varscan2
- TCERG1 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV57035020; called by muse, mutect2, varscan2
- TEX13A | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 166/203 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61147932; called by muse, mutect2, varscan2
- THRAP3 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV63566908; called by muse, mutect2, varscan2
- THSD1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1444095268, COSV51627309; called by muse, mutect2, varscan2
- TIGD2 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV57647441; called by muse, mutect2, varscan2
- TMEM45B | c.13A>C p.K5Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV55653568; called by muse, varscan2
- TMEM45B | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55653575; called by muse, varscan2
- TMPRSS11F | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs749629232, COSV62465557; called by muse, mutect2, varscan2
- TNC | c.2741G>A p.R914K | Missense Mutation (SNP) | VAF 271/688 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV60782476; called by muse, mutect2, varscan2
- TPM1 | c.591G>C p.L197F | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV51260028; called by muse, mutect2
- TRMT44 | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs372502016; called by muse, mutect2, varscan2
- TRPA1 | c.382A>C p.N128H | Missense Mutation (SNP) | VAF 132/454 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51557670; called by muse, mutect2, varscan2
- TRPM2 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV55967577; called by muse, mutect2, varscan2
- TTC39B | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52608491; called by muse, mutect2, varscan2
- UBQLNL | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564437441, COSV66492903; called by muse, mutect2, varscan2
- UBR1 | c.648A>T p.E216D | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.086); catalogued as COSV51927749; called by muse, mutect2, varscan2
- UGT3A1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1317305154, COSV57096698; called by muse, mutect2, varscan2
- UNC79 | c.2317C>T p.R773C (on ENST00000393151 / NM_001346218.2; = p.R596C on NM_020818.5) | Missense Mutation (SNP) | VAF 165/276 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781756182, COSV56376369; called by muse, mutect2, varscan2
- USH2A | c.7693C>T p.H2565Y | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1404220423, COSV56343360; called by muse, mutect2, varscan2
- VEGFC | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV54595583; called by muse, mutect2, varscan2
- VWA5A | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63707402; called by muse, mutect2, varscan2
- XIRP2 | c.8721C>G p.H2907Q (on ENST00000628543; = p.H3082Q on NM_152381.6) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54689219; called by muse, mutect2, varscan2
- ZBBX | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56785407; called by muse, mutect2, varscan2
- ZBTB22 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 79/99 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV56467733; called by muse, mutect2, varscan2
- ZC3H4 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53411366; called by muse, mutect2, varscan2
- ZFHX4 | c.7664C>T p.S2555F | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV50542768, COSV50639283; called by muse, mutect2, varscan2
- ZFHX4 | c.7750G>A p.D2584N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs774272950, COSV50639548; called by muse, mutect2, varscan2
- ZNF146 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61931441; called by muse, mutect2, varscan2
- ZNF215 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV53491467; called by muse, mutect2, varscan2
- ZNF239 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60018333; called by muse, mutect2, varscan2
- ZNF480 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs777648657, COSV57995226; called by muse, mutect2, varscan2
- ZNF556 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV56911380; called by muse, mutect2, varscan2
- ZNF746 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as rs749652098, COSV100502390; called by muse, mutect2, varscan2
- ZNF746 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.976); catalogued as COSV61406315; called by muse, mutect2, varscan2
- ZNF804A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867527468, COSV100165987, COSV56440824; called by muse, mutect2, varscan2
- ZNF813 | c.908A>C p.E303A | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV67176064; called by muse, mutect2, varscan2
- ZNF831 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs200054947, COSV64043351; called by muse, mutect2, varscan2
- ZNF835 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 215/251 reads (86%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as COSV73379253; called by muse, mutect2, varscan2
- ZNRF3 | c.394G>A p.D132N (on ENST00000544604 / NM_001206998.2; = p.D32N on NM_032173.3) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs1387123321, COSV60432271; called by muse, mutect2
- GNAQ | c.998_1011del p.D333Afs*39 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- PPP1R15A | c.1060dup p.E354Gfs*3 | Frame Shift Ins (INS) | VAF 48/82 reads (59%) | called by mutect2, pindel, varscan2
- ABCA7 | c.1887C>T p.F629= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV54026481; called by muse, mutect2, varscan2
- ACAN | c.5892C>T p.L1964= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV61356503; called by muse, mutect2, varscan2
- ACTB | c.324C>T p.A108= | Silent (SNP) | VAF 68/117 reads (58%) | catalogued as rs746032511, COSV100079915; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRG4 | c.8259C>T p.I2753= | Silent (SNP) | VAF 53/69 reads (77%) | catalogued as COSV54952154; called by muse, mutect2, varscan2
- AOC1 | c.141C>T p.F47= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as COSV62867615; called by muse, mutect2, varscan2
- AP1B1 | c.2757C>A p.P919= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV58015562; called by muse, varscan2
- ARHGAP44 | c.1230C>T p.L410= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs866366401, COSV52391142; called by muse, mutect2
- ASTN1 | c.3177C>T p.L1059= | Silent (SNP) | VAF 68/135 reads (50%) | catalogued as COSV62493780, COSV62503855; called by muse, mutect2, varscan2
- ATP11C | c.2940T>C p.L980= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV59560901; called by muse, mutect2, varscan2
- ATP6V1D | c.433C>T p.L145= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV53599102; called by muse, mutect2, varscan2
- AXL | c.633G>A p.K211= | Silent (SNP) | VAF 98/237 reads (41%) | catalogued as COSV56565516; called by muse, mutect2, varscan2
- BACH1 | c.177C>T p.F59= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV54517947; called by muse, mutect2, varscan2
- BCL6B | c.630G>A p.G210= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as rs1296985077, COSV53426941; called by muse, mutect2, varscan2
- CDA | c.261C>T p.I87= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs376525928; called by muse, mutect2, varscan2
- CIBAR2 | c.609C>T p.A203= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV73320560; called by muse, mutect2, varscan2
- CNTRL | c.3897C>A p.P1299= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV53044980, COSV53050255; called by muse, mutect2, varscan2
- COL28A1 | c.2223G>A p.R741= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as rs773116031, COSV68081243; called by muse, mutect2, varscan2
- COLEC10 | c.303G>A p.G101= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs1255960602, COSV60520822; called by muse, mutect2, varscan2
- CR1 | c.4987C>T p.L1663= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as COSV65456944; called by muse, mutect2, varscan2
- CST1 | c.150C>T p.F50= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs566215865, COSV59054825, COSV59056223; called by muse, mutect2, varscan2
- DENND11 | c.837C>T p.C279= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs1272964775, COSV72097627; called by muse, mutect2, varscan2
- DLC1 | c.21G>A p.K7= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV52296102; called by muse, mutect2, varscan2
- DNAH17 | c.1818G>A p.L606= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs775795114, COSV67751338; called by muse, mutect2, varscan2
- DSEL | c.3450G>A p.R1150= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs146176907, COSV59490249; called by muse, mutect2, varscan2
- EML3 | c.1770C>T p.S590= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV53871083; called by muse, mutect2, varscan2
- ERICH3 | c.2550G>A p.R850= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as COSV58602361; called by muse, mutect2, varscan2
- ERMN | c.672G>A p.E224= | Silent (SNP) | VAF 96/233 reads (41%) | catalogued as COSV68075107; called by muse, mutect2, varscan2
- ESRP1 | c.165G>A p.P55= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs1430164651, COSV64408520; called by muse, mutect2, varscan2
- EVPL | c.4977C>T p.L1659= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV56908851; called by muse, mutect2, varscan2
- FCRL4 | c.1008T>G p.T336= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV54860915; called by muse, mutect2, varscan2
- FER1L6 | c.2742G>A p.L914= | Silent (SNP) | VAF 47/74 reads (64%) | catalogued as COSV67548869; called by muse, mutect2, varscan2
- GCA | c.522C>T p.F174= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV52025189, COSV99280663; called by mutect2, varscan2
- GJA5 | c.30C>T p.F10= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs1350829557, COSV54783448; called by muse, mutect2, varscan2
- GJB6 | c.432C>T p.I144= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV53832093; called by muse, mutect2, varscan2
- GRK1 | c.396G>A p.A132= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs774334907, COSV59552159; called by muse, mutect2
- GRK2 | c.1302C>T p.N434= | Silent (SNP) | VAF 60/181 reads (33%) | catalogued as COSV100419737; called by muse, mutect2, varscan2
- HECW2 | c.2091G>A p.S697= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs754361809, COSV53653353; called by muse, mutect2, varscan2
- HYOU1 | c.654G>A p.R218= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV68215389; called by muse, mutect2, varscan2
- IGKV1D-16 | c.51C>T p.F17= | Silent (SNP) | VAF 82/224 reads (37%) | catalogued as rs764436841; called by muse, mutect2, varscan2
- INSC | c.1402C>T p.L468= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV65409524; called by muse, mutect2, varscan2
- INTS1 | c.2628C>T p.L876= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs765127527, COSV67176825; called by muse, mutect2, varscan2
- KCNA5 | c.1206C>T p.I402= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99364158; called by muse, mutect2, varscan2
- KRT72 | c.507G>A p.R169= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV53373616; called by muse, mutect2, varscan2
- LAMC3 | c.4434G>A p.L1478= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs868554353, COSV62653719; called by muse, mutect2, varscan2
- LILRA2 | c.474A>C p.G158= | Silent (SNP) | VAF 72/233 reads (31%) | catalogued as COSV52189721; called by muse, mutect2, varscan2
- MAGEA10 | c.936G>A p.L312= | Silent (SNP) | VAF 73/84 reads (87%) | catalogued as COSV54882901; called by muse, mutect2, varscan2
- MAS1L | c.750C>T p.F250= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV65808691; called by muse, mutect2, varscan2
- MED13 | c.6399T>A p.V2133= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV67262590; called by muse, mutect2, varscan2
- MEST | c.285G>A p.R95= | Silent (SNP) | VAF 106/492 reads (22%) | catalogued as COSV56227814; called by muse, mutect2, varscan2
- MGAM | c.4158C>T p.F1386= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV72073887, COSV72074103; called by muse, mutect2, varscan2
- NAB2 | c.1077C>T p.S359= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1047137055, COSV100272779; called by muse, mutect2, varscan2
- NCKAP1L | c.1395C>T p.I465= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV53204822; called by muse, mutect2, varscan2
- NCOA2 | c.2466C>T p.F822= | Silent (SNP) | VAF 91/163 reads (56%) | catalogued as COSV51218679; called by muse, mutect2, varscan2
- NCOA6 | c.4674C>T p.S1558= | Silent (SNP) | VAF 76/237 reads (32%) | catalogued as COSV62862286; called by muse, mutect2, varscan2
- NLRP1 | c.1863C>T p.F621= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV52561444; called by muse, mutect2, varscan2
- NPSR1 | c.213T>A p.L71= | Silent (SNP) | VAF 55/158 reads (35%) | catalogued as COSV100707090; called by muse, mutect2, varscan2
- NR1H3 | c.948C>T p.L316= | Silent (SNP) | VAF 94/236 reads (40%) | catalogued as COSV68008229; called by muse, mutect2, varscan2
- NT5C1B | c.870C>T p.Y290= (on ENST00000359846 / NM_001199086.2; = p.Y230= on NM_033253.4) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs746909085, COSV58394165; called by muse, mutect2, varscan2
- OR52B6 | c.519C>T p.I173= | Silent (SNP) | VAF 138/320 reads (43%) | catalogued as COSV61447575; called by muse, mutect2, varscan2
- OR5M10 | c.765C>T p.L255= | Silent (SNP) | VAF 66/189 reads (35%) | catalogued as COSV73242273; called by muse, mutect2, varscan2
- OR6C1 | c.938G>A p.*313= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as COSV101110569, COSV65572992; called by muse, mutect2, varscan2
- OR6C4 | c.498C>T p.F166= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV101263143, COSV67792839, COSV67792888; called by muse, mutect2, varscan2
- OR7A10 | c.201C>T p.S67= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV50166175, COSV99932448; called by muse, mutect2, varscan2
- OR7D2 | c.159C>T p.S53= | Silent (SNP) | VAF 74/195 reads (38%) | catalogued as COSV60139315; called by muse, mutect2, varscan2
- PAK5 | c.1893C>T p.I631= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV62023809; called by muse, mutect2, varscan2
- PAM | c.2739T>C p.F913= (on ENST00000438793 / NM_001319943.1; = p.F914= on NM_000919.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as COSV57210886; called by muse, mutect2, varscan2
- PCDHGB5 | c.1401C>T p.I467= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs749580875, COSV53918013; called by muse, mutect2, varscan2
- PCNX1 | c.5145G>A p.E1715= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as COSV53091428; called by muse, mutect2, varscan2
- PGS1 | c.993T>G p.L331= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV53144159; called by muse, mutect2, varscan2
- PLIN4 | c.696G>A p.V232= (on ENST00000301286; = p.V247= on NM_001367868.2) | Silent (SNP) | VAF 143/320 reads (45%) | catalogued as COSV56689009; called by muse, mutect2, varscan2
- POU2F1 | c.495C>T p.P165= (on ENST00000541643 / NM_001365848.1; = p.P188= on NM_002697.4) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs941772411, COSV54814374; called by muse, mutect2, varscan2
- PPP6R3 | c.958C>T p.L320= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as COSV55723296; called by muse, mutect2, varscan2
- PSMD11 | c.945T>C p.D315= | Silent (SNP) | VAF 83/217 reads (38%) | catalogued as COSV55577916; called by muse, mutect2, varscan2
- PXDNL | c.2040C>T p.L680= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV62482991, COSV62496394; called by muse, mutect2, varscan2
- RAC2 | c.294C>T p.F98= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as COSV50774045, COSV99969421; called by muse, mutect2, varscan2
- RETNLB | c.51G>A p.L17= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV55465265; called by muse, varscan2
- RNF17 | c.3801T>G p.T1267= | Silent (SNP) | VAF 69/327 reads (21%) | catalogued as COSV55036564; called by muse, mutect2
- RPTOR | c.1284C>T p.N428= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as COSV100157108; called by muse, mutect2, varscan2
- RYR2 | c.6288G>A p.G2096= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV63672427; called by muse, mutect2, varscan2
- RYR2 | c.6522C>T p.V2174= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV63672440, COSV63715537; called by muse, mutect2, varscan2
- SEMA4B | c.693C>T p.S231= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV60172886; called by muse, mutect2
- SLC12A9 | c.477C>T p.V159= | Silent (SNP) | VAF 76/158 reads (48%) | catalogued as COSV51932167; called by muse, mutect2, varscan2
- SLC22A10 | c.1542C>T p.L514= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as rs984694224, COSV60420640; called by muse, mutect2, varscan2
- SPTBN1 | c.2211G>A p.K737= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV61686729; called by muse, mutect2, varscan2
- SUPT5H | c.3231C>T p.N1077= | Silent (SNP) | VAF 72/87 reads (83%) | catalogued as COSV58679024; called by muse, mutect2, varscan2
- SYT4 | c.1020G>A p.K340= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs774250318, COSV54899212; called by muse, mutect2, varscan2
- TBC1D22B | c.612G>A p.R204= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV65142496; called by muse, mutect2, varscan2
- THRAP3 | c.102C>T p.S34= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV100663576; called by muse, mutect2, varscan2
- TTN | c.71346C>T p.F23782= (on ENST00000591111; = p.F16358= on NM_003319.4) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV59951409; called by muse, mutect2, varscan2
- TTN | c.71184C>T p.L23728= (on ENST00000591111; = p.L16304= on NM_003319.4) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV59951451; called by muse, mutect2, varscan2
- TTN | c.60174G>A p.K20058= (on ENST00000591111; = p.K12634= on NM_003319.4) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs778285104, COSV59951478; called by muse, mutect2
- TUBGCP3 | c.1851C>T p.I617= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV56185381; called by muse, mutect2, varscan2
- UCMA | c.135G>A p.Q45= | Silent (SNP) | VAF 54/74 reads (73%) | catalogued as rs767861412, COSV66321392; called by muse, mutect2, varscan2
- UNC79 | c.1485C>T p.H495= (on ENST00000393151 / NM_001346218.2; = p.H318= on NM_020818.5) | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs769051221, COSV56379871, COSV56400516; called by muse, mutect2, varscan2
- VWA3A | c.1246C>T p.L416= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs1043875851, COSV55389196; called by muse, mutect2, varscan2
- WDR49 | c.1032A>G p.R344= (on ENST00000308378 / NM_001366158.1; = p.R685= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV57704944; called by muse, mutect2, varscan2
- WNT7A | c.1032G>A p.E344= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs897161195, COSV53197490; called by muse, mutect2, varscan2
- ZNF208 | c.285C>T p.F95= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV68102628; called by muse, mutect2, varscan2
- ZNF282 | c.870C>T p.S290= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100021925, COSV50479378; called by muse, mutect2, varscan2
- ZNF644 | c.3579C>T p.I1193= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV61346590, COSV61349541; called by muse, mutect2, varscan2
- CD300LD | chr17:74592390 A>T | 5'Flank (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.241C>T | RNA (SNP) | VAF 46/218 reads (21%) | called by muse, varscan2
- IGKV1-13 | n.165T>C | RNA (SNP) | VAF 80/103 reads (78%) | called by muse, varscan2
- MIR206 | n.40G>A | RNA (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2, varscan2
- MIR770 | n.51G>A | RNA (SNP) | VAF 29/54 reads (54%) | catalogued as rs1228867194; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+60G>A | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as COSV65365803; called by muse, mutect2, varscan2
- POLA1 | c.2947-21142C>T | Intron (SNP) | VAF 114/133 reads (86%) | called by muse, mutect2, varscan2
- SND1 | c.1779+6708_1779+6710del | Intron (DEL) | VAF 117/634 reads (18%) | called by mutect2, pindel, varscan2
